Somatic mutation profile of tumor specimen TCGA-CN-4738-01A (aliquot TCGA-CN-4738-01A-02D-1512-08) from TCGA case TCGA-CN-4738, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 53.7 years (19,621 days).
Specimen TCGA-CN-4738-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25ec2691-d87c-40cb-91d2-3f422274f834.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-4738-10A (Blood Derived Normal), aliquot TCGA-CN-4738-10A-01D-1512-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2611e117-9e6e-4a9e-9520-99a2cc9779d9

The open-access MAF lists 99 somatic variants for this specimen: 67 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 29, Nonsense Mutation 5, Intron 2, Splice Site 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913386, CM983988, COSV58683051, COSV58690307, COSV58692178; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 7/131 reads (5%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2
- ACTN2 | c.992A>G p.K331R | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63979164; called by muse, mutect2, varscan2
- ANAPC1 | c.80A>G p.H27R | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.966); catalogued as rs1428560212, COSV100594504; called by muse, mutect2, varscan2
- ANGPT2 | c.798C>A p.N266K | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV100290592; called by muse, mutect2, varscan2
- APOL6 | c.332C>T p.T111I | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV101290984; called by muse, mutect2
- BPIFB1 | c.671C>A p.S224Y | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV53607244, COSV99487184; called by muse, mutect2, varscan2
- CA5B | c.487A>T p.R163* | Nonsense Mutation (SNP) | VAF 4/59 reads (7%) | catalogued as COSV100590678; called by muse, mutect2
- CACNA1S | c.1882G>A p.G628S | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs768445692, COSV62945520; ClinVar: uncertain significance; called by muse, mutect2
- CCDC63 | c.489+1G>A p.X163_splice | Splice Site (SNP) | VAF 34/196 reads (17%) | catalogued as rs372717046; called by muse, mutect2, varscan2
- CHAF1A | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.474); catalogued as rs767544087, COSV56676464; called by muse, mutect2, varscan2
- CNTNAP2 | c.148A>T p.S50C | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62260821; called by muse, mutect2, varscan2
- DCAF12L1 | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64421804; called by muse, mutect2, varscan2
- DDB1 | c.3346G>T p.D1116Y | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as rs959859422, COSV100074250; called by muse, mutect2, varscan2
- DGKZ | c.2711G>A p.W904* (on ENST00000454345 / NM_001105540.2; = p.W716* on NM_003646.4) | Nonsense Mutation (SNP) | VAF 42/264 reads (16%) | catalogued as COSV100551031; called by muse, mutect2, varscan2
- DMXL2 | c.7558C>T p.H2520Y | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.259); catalogued as COSV99195950; called by muse, mutect2, varscan2
- DNAH7 | c.2534G>A p.C845Y | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs1483034215, COSV100413776; called by muse, mutect2, varscan2
- DYNLRB1 | c.269T>C p.V90A | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV100848974; called by muse, mutect2, varscan2
- ELMOD3 | c.593A>G p.D198G | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV100226042; called by muse, mutect2, varscan2
- GABRB2 | c.1255G>C p.E419Q (on ENST00000274547; = p.E381Q on NM_000813.3) | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.783); catalogued as COSV99195642; called by muse, mutect2
- GLMN | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.19); catalogued as COSV64860070; called by muse, mutect2
- GPR158 | c.2899C>A p.P967T | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV66269625, COSV66276035; called by muse, mutect2
- GRIK2 | c.507G>A p.W169* | Nonsense Mutation (SNP) | VAF 7/142 reads (5%) | catalogued as COSV59784768; called by muse, mutect2
- HECTD1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as rs1169523562, COSV101237297; called by muse, mutect2
- HFM1 | c.2995A>T p.S999C | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as rs1383805542, COSV99645312; called by muse, mutect2, varscan2
- HR | c.102T>G p.D34E | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as COSV100455627; called by muse, mutect2, varscan2
- ICA1 | c.497A>G p.Y166C | Missense Mutation (SNP) | VAF 43/254 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99654822; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1268C>G p.T423S | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100145048; called by muse, mutect2, varscan2
- LINGO2 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs778347323, COSV58061692; called by muse, mutect2, varscan2
- LINGO4 | c.550A>T p.T184S | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV100561790; called by muse, mutect2, varscan2
- LRP1 | c.5875G>T p.V1959L | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as rs144804370; called by muse, mutect2, varscan2
- LRRK2 | c.1138T>G p.Y380D | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); catalogued as COSV100109136; called by muse, mutect2
- MAPKAPK5 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs947286159, COSV101534701; called by muse, mutect2
- MYH11 | c.5268C>A p.S1756R | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV100257642; called by muse, mutect2, varscan2
- MYOM1 | c.2138G>T p.R713L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99865161; called by muse, mutect2, varscan2
- NPEPL1 | c.320C>A p.A107E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV100622320; called by muse, mutect2
- OR2D2 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.632); catalogued as COSV100203712; called by muse, mutect2, varscan2
- OR8J1 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100274853, COSV57317649; called by muse, mutect2, varscan2
- PLPPR4 | c.644A>G p.Y215C | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100926688; called by muse, mutect2
- POLD3 | c.527G>A p.G176D | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99737569; called by muse, mutect2, varscan2
- POLL | c.332A>G p.K111R | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV100150023; called by muse, mutect2, varscan2
- PROZ | c.672G>T p.R224S | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.92); PolyPhen benign (0.012); catalogued as COSV100720262; called by muse, mutect2
- PSD | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as COSV50052477; called by muse, mutect2
- PTPN23 | c.3879G>C p.E1293D | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99650172; called by muse, mutect2, varscan2
- PTPN4 | c.1900C>G p.Q634E | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99749470; called by muse, mutect2, varscan2
- PTPRU | c.3641C>T p.P1214L | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1472676297, COSV60523321; called by muse, mutect2, varscan2
- RIMS2 | c.1397T>C p.V466A (on ENST00000666250 / NM_001348490.2; = p.V274A on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99158462; called by muse, mutect2, varscan2
- RPS6KA4 | c.691C>A p.L231M | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.987); catalogued as COSV99589764; called by muse, mutect2
- SALL2 | c.1364C>A p.S455Y | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100444103; called by muse, mutect2, varscan2
- SCNN1A | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV99964476; called by muse, mutect2
- SLC2A13 | c.613A>G p.R205G | Missense Mutation (SNP) | VAF 25/257 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99785865; called by muse, mutect2, varscan2
- SLC5A3 | c.954G>A p.M318I | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100757758; called by muse, mutect2
- SLC8A3 | c.1829G>A p.R610K | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99385268; called by muse, mutect2, varscan2
- SLITRK3 | c.1977C>A p.S659R | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99578471; called by muse, mutect2, varscan2
- SYNE1 | c.23949T>G p.I7983M (on ENST00000367255 / NM_182961.4; = p.I7912M on NM_033071.3) | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99552531; called by muse, mutect2
- SYNGAP1 | c.3902C>T p.P1301L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs199694815, COSV99537810; called by muse, mutect2, varscan2
- TLR7 | c.2140G>A p.V714I | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.148); catalogued as COSV101027710; called by muse, mutect2, varscan2
- TMEM132B | c.1469A>G p.K490R | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV100168456; called by muse, mutect2, varscan2
- TRERF1 | c.1367C>A p.P456H | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as rs775289882, COSV100549931; called by muse, mutect2, varscan2
- TRO | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV51502808, COSV99435726; called by muse, mutect2
- TTN | c.15909T>G p.N5303K (on ENST00000591111; = p.N4376K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/276 reads (8%) | PolyPhen possibly damaging (0.6); catalogued as COSV100593348; called by muse, mutect2
- VN1R2 | c.629G>A p.G210D | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.599); catalogued as COSV100447769; called by muse, mutect2
- ZKSCAN5 | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as rs141273536; called by muse, mutect2
- ZMAT1 | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.106); catalogued as COSV100858663; called by muse, mutect2, varscan2
- ZNF99 | c.2111C>G p.P704R | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV101233690, COSV68055964; called by muse, mutect2, varscan2
- AJUBA | c.1047_1050dup p.A351Qfs*39 | Frame Shift Ins (INS) | VAF 37/176 reads (21%) | called by mutect2, pindel, varscan2
- BIRC6 | c.9610G>T p.E3204* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- ALMS1 | c.2502T>A p.A834= | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as COSV100041073; called by muse, mutect2, varscan2
- CCDC24 | c.585C>T p.C195= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV100746026; called by muse, mutect2
- CENPE | c.5703C>G p.L1901= | Silent (SNP) | VAF 7/158 reads (4%) | catalogued as COSV99476951; called by muse, mutect2
- CENPO | c.579G>A p.Q193= | Silent (SNP) | VAF 26/156 reads (17%) | catalogued as rs763882377, COSV99567616; called by muse, mutect2, varscan2
- CFAP58 | c.1590A>G p.K530= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV100866028; called by muse, mutect2
- CLVS2 | c.757C>T p.L253= | Silent (SNP) | VAF 12/178 reads (7%) | catalogued as COSV99252108; called by muse, mutect2
- CST1 | c.153C>T p.A51= | Silent (SNP) | VAF 23/134 reads (17%) | catalogued as COSV100494289; called by muse, mutect2, varscan2
- DENND2B | c.633G>A p.P211= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100567113; called by muse, mutect2, varscan2
- FLG2 | c.3867A>G p.S1289= | Silent (SNP) | VAF 56/401 reads (14%) | catalogued as COSV101165585; called by muse, mutect2, varscan2
- FLOT2 | c.657C>T p.F219= | Silent (SNP) | VAF 15/128 reads (12%) | catalogued as rs1461041007, COSV67528954; called by muse, mutect2, varscan2
- GPATCH2 | c.537G>A p.R179= | Silent (SNP) | VAF 28/234 reads (12%) | catalogued as COSV100861335; called by muse, mutect2, varscan2
- HIRA | c.2838C>T p.L946= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs1357968760, COSV99599878; called by muse, mutect2, varscan2
- IKZF3 | c.766C>T p.L256= | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as COSV53106831; called by muse, varscan2
- MICAL2 | c.549C>T p.F183= | Silent (SNP) | VAF 21/206 reads (10%) | catalogued as rs758276297, COSV56316806; called by muse, mutect2, varscan2
- NCBP1 | c.963C>T p.I321= | Silent (SNP) | VAF 27/178 reads (15%) | catalogued as COSV100912526; called by muse, mutect2, varscan2
- NRSN2 | c.243C>T p.T81= | Silent (SNP) | VAF 24/159 reads (15%) | catalogued as COSV101206782; called by muse, mutect2, varscan2
- NTRK3 | c.1680C>A p.L560= | Silent (SNP) | VAF 42/178 reads (24%) | catalogued as COSV100712237, COSV62315920; called by muse, varscan2
- OR52A5 | c.834C>T p.L278= | Silent (SNP) | VAF 21/123 reads (17%) | catalogued as COSV100263287; called by muse, mutect2, varscan2
- OTOA | c.195G>T p.T65= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV53758334, COSV99623521; called by muse, mutect2, varscan2
- PCDH11X | c.2310G>T p.L770= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as COSV100008035; called by muse, mutect2, varscan2
- POU3F2 | c.1122C>G p.L374= | Silent (SNP) | VAF 7/120 reads (6%) | catalogued as COSV100098955; called by muse, mutect2
- PTPRU | c.3642G>C p.P1214= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as rs377688027, COSV100111483; called by muse, mutect2, varscan2
- SIGIRR | c.687G>C p.S229= | Silent (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- SPTBN2 | c.1767C>T p.A589= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs748966229, COSV100018143; called by muse, mutect2, varscan2
- TEX55 | c.1206C>T p.L402= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV99817284; called by muse, mutect2, varscan2
- TMEM123 | c.309C>G p.V103= | Silent (SNP) | VAF 32/366 reads (9%) | catalogued as rs142725847; called by muse, mutect2
- TMEM196 | c.345C>T p.I115= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as rs750398997, COSV68254190; called by muse, mutect2, varscan2
- UBE4B | c.2520G>A p.L840= (on ENST00000343090 / NM_001105562.3; = p.L711= on NM_006048.5) | Silent (SNP) | VAF 17/134 reads (13%) | catalogued as rs546274495, COSV99475662; called by muse, mutect2, varscan2
- ZNF436 | c.879C>T p.L293= | Silent (SNP) | VAF 15/166 reads (9%) | catalogued as COSV100011187, COSV58358016, COSV58358716; called by muse, mutect2
- FBXL13 | c.496-5546T>A | Intron (SNP) | VAF 12/81 reads (15%) | catalogued as COSV100501135; called by muse, mutect2, varscan2
- PCDHA2 | c.2388+54C>G | Intron (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100973550; called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827973 C>A | 3'Flank (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100157314; called by muse, mutect2, varscan2
